TCGA case TCGA-06-0175 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/22297a8b-4761-4f5c-b080-60a39c3a0670

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Dead; Days to death: 123 days.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 70.0 years (25,559 days); Year of diagnosis: 2003; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Tipifarnib; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 22 days; Number of cycles: 1.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 51 days; Days to treatment end: 78 days; Treatment dose: 5,900 cGy; Number of fractions: 22; Treatment anatomic sites: Primary Tumor Field.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 70.1 years (25,598 days); Days to diagnosis: 39 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 39 (post initial treatment): Progression or recurrence: Yes; Days to progression: 39 days.
- Days to follow up: 83 days; Disease response: With Tumor.
- Days to follow up: 123 days; Disease response: With Tumor.
- Karnofsky performance status: 100; Timepoint: Preoperative.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0175-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.3; Intermediate dimension: 0.9; Shortest dimension: 0.9.
  Slide TCGA-06-0175-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50.
  Slide TCGA-06-0175-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment: Pharmaceutical therapy drug name: Tipifarnib (R115777).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 123 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 123 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 39 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-06-0175-01): tumor purity 0.73, ploidy 2.02, whole-genome doublings 0 (call status: legacy_call).
